Somatic mutation profile of tumor specimen ALCH-B2OK-TTP1-A (aliquot ALCH-B2OK-TTP1-A-1-0-D-A77P-36) from ALCHEMIST case ALCH-B2OK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.7 years (23,632 days).
Specimen ALCH-B2OK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0eeb3eb5-d472-4902-9f53-26a6becb6ae5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2OK-NB1-A (Blood Derived Normal), aliquot ALCH-B2OK-NB1-A-1-0-D-A77P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/260124bd-e546-4b89-8fd4-f833d984634c

The open-access MAF lists 62 somatic variants for this specimen: 37 protein-altering or splice-affecting, 18 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 18, Intron 4, Nonsense Mutation 2, 3'UTR 1, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3581C>G p.S1194* | Nonsense Mutation (SNP) | VAF 14/246 reads (6%) | catalogued as CM040004, CM970088, COSV57339248; called by muse, mutect2
- ASPM | c.8057A>C p.Q2686P | Missense Mutation (SNP) | VAF 20/361 reads (6%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.845); catalogued as COSV99660602; called by muse, mutect2
- CHST6 | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 48/240 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.366); catalogued as rs751949248, COSV60001546; ClinVar: uncertain significance; called by mutect2, varscan2
- CNTN5 | c.114G>C p.K38N | Missense Mutation (SNP) | VAF 46/614 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as COSV54335485; called by muse, mutect2
- CNTNAP4 | c.1617C>A p.F539L | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV56695362; called by muse, mutect2
- DNAH11 | c.6325G>T p.D2109Y | Missense Mutation (SNP) | VAF 44/382 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760217754, COSV60954001; called by muse, mutect2, varscan2
- GCNT2 | c.809C>A p.T270K | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs761096313; called by muse, mutect2, varscan2
- MN1 | c.3413C>T p.P1138L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as rs1283185960; called by muse, mutect2, varscan2
- MYB | c.1139G>A p.G380D | Missense Mutation (SNP) | VAF 42/312 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.271); catalogued as rs769038941; called by muse, mutect2, varscan2
- OR2B11 | c.746T>G p.L249R | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs781136061; called by muse, mutect2
- PCDHA9 | c.1504C>T p.R502C | Missense Mutation (SNP) | VAF 40/314 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs1554143600; called by muse, mutect2, varscan2
- PCDHB10 | c.1898G>A p.R633H | Missense Mutation (SNP) | VAF 32/297 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.479); catalogued as rs1428124124; called by muse, mutect2
- PCNT | c.1181T>C p.I394T | Missense Mutation (SNP) | VAF 18/330 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as rs200545088; called by muse, mutect2
- PKD1 | c.3286G>A p.A1096T | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0.01); catalogued as rs1307673492; called by muse, mutect2, varscan2
- RASIP1 | c.1643G>A p.R548Q | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.033); catalogued as rs932292340; called by muse, mutect2
- TMEM131 | c.5446G>A p.A1816T | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs764378595, COSV51774474; called by muse, mutect2, varscan2
- ARMC2 | c.1843G>C p.A615P | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.773); called by muse, varscan2
- BANK1 | c.1409A>G p.H470R | Missense Mutation (SNP) | VAF 22/366 reads (6%) | SIFT tolerated (0.68); PolyPhen benign (0.001); called by muse, mutect2
- BTG3 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2
- CP | c.1319G>A p.G440D | Missense Mutation (SNP) | VAF 39/384 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- ECHDC1 | c.718A>T p.K240* (on ENST00000531967 / NM_001139510.1; = p.K234* on NM_001002030.2) | Nonsense Mutation (SNP) | VAF 11/179 reads (6%) | called by muse, mutect2
- FAM47C | c.2933G>T p.G978V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- GAD1 | c.1753G>A p.E585K | Missense Mutation (SNP) | VAF 13/194 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); called by muse, mutect2
- HBP1 | c.385T>G p.S129A | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2
- HOXD10 | c.922A>T p.R308W | Missense Mutation (SNP) | VAF 30/208 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MGAM2 | c.5467A>C p.I1823L | Missense Mutation (SNP) | VAF 11/288 reads (4%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); called by muse, mutect2
- MKKS | c.886G>T p.V296F | Missense Mutation (SNP) | VAF 18/425 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MYO15A | c.3626A>G p.N1209S | Missense Mutation (SNP) | VAF 7/178 reads (4%) | SIFT tolerated (0.63); PolyPhen benign (0.015); called by muse, mutect2
- MYOC | c.1396C>G p.P466A | Missense Mutation (SNP) | VAF 30/506 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); called by muse, mutect2
- NCAN | c.3088T>G p.Y1030D | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- PABPC3 | c.326C>G p.S109C | Missense Mutation (SNP) | VAF 19/272 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); called by muse, mutect2
- RPS3 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 30/225 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- SYNE2 | c.19764A>C p.E6588D | Missense Mutation (SNP) | VAF 84/233 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- THAP8 | c.207G>C p.W69C | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TKTL1 | c.964T>C p.S322P | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ZNF469 | c.6721A>G p.T2241A (on ENST00000437464; = p.T2269A on NM_001367624.2) | Missense Mutation (SNP) | VAF 39/340 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- ZZEF1 | c.2895G>T p.W965C | Missense Mutation (SNP) | VAF 9/196 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.379); called by muse, mutect2
- CCNB3 | c.147T>C p.S49= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as rs1483310158; called by muse, mutect2, varscan2
- CD68 | c.207C>T p.T69= | Silent (SNP) | VAF 17/148 reads (11%) | catalogued as rs779474397; called by muse, mutect2, varscan2
- CDH11 | c.2349A>G p.A783= | Silent (SNP) | VAF 18/110 reads (16%) | catalogued as COSV99218958; called by muse, mutect2
- DUSP29 | c.555G>A p.P185= | Silent (SNP) | VAF 16/127 reads (13%) | catalogued as rs762330745, COSV58300737; called by muse, mutect2, varscan2
- FLNC | c.1071G>A p.Q357= | Silent (SNP) | VAF 14/211 reads (7%) | called by muse, mutect2
- FNDC1 | c.1254T>G p.T418= | Silent (SNP) | VAF 8/112 reads (7%) | called by muse, mutect2
- FREM2 | c.2487A>G p.P829= | Silent (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2, varscan2
- ITM2B | c.747C>T p.F249= | Silent (SNP) | VAF 16/300 reads (5%) | catalogued as rs765077508, COSV66034801; called by muse, mutect2
- ITPRID1 | c.3093A>G p.S1031= | Silent (SNP) | VAF 12/142 reads (8%) | called by muse, mutect2
- KIF26A | c.3264T>C p.S1088= | Silent (SNP) | VAF 14/64 reads (22%) | called by muse, mutect2
- MYH7B | c.5769C>T p.V1923= | Silent (SNP) | VAF 7/186 reads (4%) | called by muse, mutect2
- PAWR | c.616T>C p.L206= | Silent (SNP) | VAF 10/108 reads (9%) | catalogued as COSV60922519; called by muse, mutect2
- PCNX2 | c.6252G>A p.E2084= | Silent (SNP) | VAF 4/58 reads (7%) | catalogued as rs1300389271; called by muse, mutect2
- SEMA3G | c.2037G>A p.L679= | Silent (SNP) | VAF 17/129 reads (13%) | catalogued as COSV99202265; called by muse, mutect2, varscan2
- SERPINA3 | c.270G>A p.G90= | Silent (SNP) | VAF 33/306 reads (11%) | catalogued as rs745752138, COSV67586372; called by muse, mutect2, varscan2
- TCFL5 | c.1161G>T p.G387= | Silent (SNP) | VAF 123/311 reads (40%) | called by muse, mutect2, varscan2
- THSD7B | c.1440T>A p.P480= | Silent (SNP) | VAF 18/115 reads (16%) | called by muse, mutect2, varscan2
- TRIM41 | c.657C>T p.S219= | Silent (SNP) | VAF 16/206 reads (8%) | called by muse, mutect2
- CCDC175 | c.2305+113A>C | Intron (SNP) | VAF 17/49 reads (35%) | called by muse, mutect2, varscan2
- CDH15 | chr16:89168603 T>C | 5'Flank (SNP) | VAF 10/46 reads (22%) | called by muse, mutect2, varscan2
- OOSP2 | c.348-224A>T | Intron (SNP) | VAF 15/87 reads (17%) | called by muse, varscan2
- RN7SL484P | chr15:99791735 C>A | 3'Flank (SNP) | VAF 16/242 reads (7%) | called by muse, mutect2
- RNF170 | c.*1072G>C | 3'UTR (SNP) | VAF 32/650 reads (5%) | catalogued as rs1563653441; called by muse, mutect2
- SUGCT | c.1089+2776T>G | Intron (SNP) | VAF 13/134 reads (10%) | called by muse, mutect2, varscan2
- TUBA1B | c.4-614C>T | Intron (SNP) | VAF 14/104 reads (13%) | called by muse, mutect2, varscan2
